CCDI case PBCNHH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/85f23823-1abd-46d3-89ab-ca64602515be

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,550 days).

Biospecimens (3 samples)
- Sample 0DVZ0P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ11: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVZ1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
